Somatic mutation profile of tumor specimen TCGA-KK-A59X-01A (aliquot TCGA-KK-A59X-01A-11D-A29Q-08) from TCGA case TCGA-KK-A59X, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,416 days).
Specimen TCGA-KK-A59X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a0b4556-fb05-4d55-98dd-4f83cffe5c74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A59X-11A (Solid Tissue Normal), aliquot TCGA-KK-A59X-11A-21D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1da20da0-1359-487f-a188-9689e51dc285

The open-access MAF lists 47 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 31, Silent 7, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1064A>T p.D355V | Missense Mutation (SNP) | VAF 38/64 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684573, COSV61686129, COSV61697475; called by muse, varscan2
- SPOP | c.305T>G p.F102C | Missense Mutation (SNP) | VAF 58/120 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920894, COSV61652830, COSV61654088, COSV61654168; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- AKAP9 | c.5348G>T p.R1783L (on ENST00000359028; = p.R1751L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.245); catalogued as COSV62337694, COSV62340081; called by muse, mutect2, varscan2
- ARFGEF3 | c.2989C>G p.L997V | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52450238; called by muse, mutect2, varscan2
- C1S | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.026); catalogued as COSV61070059; called by muse, mutect2, varscan2
- CAMK2D | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56426039; called by muse, mutect2, varscan2
- CCPG1 | c.2207A>G p.H736R | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0.271); catalogued as COSV51241139; called by muse, mutect2, varscan2
- CDK12 | c.3196T>C p.S1066P | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747832521, COSV70999291; called by muse, mutect2, varscan2
- CEACAM16 | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV69186163; called by muse, mutect2, varscan2
- CHRNB4 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55714681; called by muse, mutect2, varscan2
- DDX17 | c.1622A>G p.N541S | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as rs546476409, COSV53246498; called by muse, mutect2, varscan2
- DEF6 | c.848T>G p.V283G | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57353090; called by muse, mutect2, varscan2
- DNAH8 | c.11207T>C p.I3736T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59425302; called by muse, mutect2, varscan2
- EMILIN1 | c.1353del p.L452Cfs*5 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as COSV53155402; called by mutect2, pindel, varscan2
- ESR1 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 52/147 reads (35%) | catalogued as COSV52782235; called by muse, mutect2, varscan2
- ISLR2 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62301644; called by muse, mutect2, varscan2
- KIF13A | c.4150A>G p.S1384G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52442873; called by muse, mutect2, varscan2
- KMT2C | c.2554A>G p.T852A | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as COSV51292248; called by muse, varscan2
- LEF1 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 201/476 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54463492; called by muse, mutect2, varscan2
- MMP9 | c.656C>A p.P219Q | Missense Mutation (SNP) | VAF 193/538 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV63433757; called by muse, mutect2, varscan2
- MRPS2 | c.169+2T>A p.X57_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | catalogued as COSV54092176; called by muse, mutect2
- MYBPC2 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs368536456; called by muse, mutect2, varscan2
- OPA3 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 122/255 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55605905; called by muse, mutect2, varscan2
- PIDD1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs200829634, COSV61704182; called by muse, mutect2, varscan2
- ROBO1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs920236659, COSV71391743, COSV71398442, COSV71398684; called by muse, mutect2, varscan2
- RUNDC3A | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs1417453697, COSV56637017; called by muse, mutect2, varscan2
- RUNX1T1 | c.850T>C p.Y284H (on ENST00000265814 / NM_001198628.1; = p.Y257H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV56137818, COSV56165558; called by muse, mutect2, varscan2
- RUVBL2 | c.1121+1G>T p.X374_splice | Splice Site (SNP) | VAF 40/114 reads (35%) | catalogued as COSV55484219; called by muse, mutect2, varscan2
- SEPHS1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs1258469101, COSV59257147; called by muse, mutect2, varscan2
- SIGLEC1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.192); catalogued as COSV52458654; called by muse, mutect2, varscan2
- SLC38A8 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs930213649, COSV55304722; called by muse, mutect2, varscan2
- TCEAL3 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV54580072; called by muse, mutect2, varscan2
- TGFBR3 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53021729, COSV53022789; called by muse, mutect2, varscan2
- VAV1 | c.513C>G p.D171E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.239); catalogued as COSV58378713, COSV58393430; called by muse, mutect2, varscan2
- WSB2 | c.1136G>C p.S379T | Missense Mutation (SNP) | VAF 95/271 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV57476864; called by muse, mutect2, varscan2
- YTHDC2 | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV50736645; called by muse, mutect2, varscan2
- FASTKD1 | c.1704C>T p.I568= | Splice Region (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- IL6ST | c.657del p.V220* | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- IRF4 | c.578_579dup p.C194Nfs*4 | Frame Shift Ins (INS) | VAF 102/276 reads (37%) | called by mutect2, pindel, varscan2
- VLDLR | c.855_856del p.C285* | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | called by pindel, varscan2
- ADAM2 | c.1356C>T p.C452= | Silent (SNP) | VAF 103/236 reads (44%) | catalogued as rs760989103, COSV55858883, COSV55866251; called by muse, mutect2, varscan2
- DRC7 | c.759C>T p.D253= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs1448594858, COSV61052973; called by muse, mutect2, varscan2
- EDDM3A | c.129A>G p.R43= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as rs1203780076, COSV58794778; called by muse, mutect2, varscan2
- HAUS1 | c.138C>T p.V46= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as COSV56359428; called by muse, mutect2, varscan2
- SLC4A9 | c.1218C>T p.D406= (on ENST00000507527 / NM_001258428.2; = p.D382= on NM_031467.3) | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs1451675164, COSV50183801; called by muse, mutect2, varscan2
- UTRN | c.5352T>C p.N1784= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV62328738; called by muse, mutect2, varscan2
- ZZEF1 | c.5169A>G p.Q1723= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs981343994, COSV67555951; called by muse, mutect2, varscan2
